CPTAC case C3L-02601 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bf3941c0-1430-4b99-8d2e-b0e685cbf0b1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1946; Vital status: Dead; Days to death: 201 days; Year of death: 2018; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 71.5 years (26,133 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 201 days; Progression or recurrence: yes; Days to recurrence: 182 days; Days to last follow up: 201 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2 cm (a second GDC size field records 4.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 5; Margin status: Uninvolved.

Follow-up (2 entries)
- Days to follow up: 193 days; Disease response: With Tumor.
- Days to follow up: 201 days; Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 182 days.

Other clinical attributes
- Weight: 104 kg; Height: 182 cm; BMI: 31.4; Comorbidities: Pancreatitis; DLCO (% of predicted): 65; FEV1/FVC after bronchodilator (%): 71; FEV1/FVC before bronchodilator (%): 71; FEV1 after bronchodilator (% of reference): 69; FEV1 before bronchodilator (% of reference): 70.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 6; Cigarettes per day: 2; Tobacco smoking onset year: 1957; Exposure duration years: 65.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02601-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 365 mg; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02601-21: Section location: Left Upper Lobe; Percent tumor nuclei: 70; Percent necrosis: 0.
- Sample C3L-02601-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 391 mg; Time between excision and freezing: 13 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02601-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
